Surgical pathology report (de-identified scan), TCGA case TCGA-VP-A87J, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Washington University, specimen TCGA-VP-A87J-01A (Primary Tumor).

[page 1 of 4]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

ICD-O 3.
Adenocarcinoma, acinar
8140/3
Site Prostate NOS
C61.9

Jan 11/21/13

SURGICAL PATHOLOGY REPORT

FINAL

Patient Name: [REDACTED]
Address: [REDACTED] Service: [REDACTED] Accession #: [REDACTED]
Gender: M Location: [REDACTED]
DOB: [REDACTED] MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Physician(s):

DIAGNOSIS:

PROSTATE, RADICAL PROSTATECTOMY

- ADENOCARCINOMA, GLEASON GRADE 3+4 = SCORE 7 IN THE RIGHT APEX AND THE RIGHT AND LEFT BASES, AND INVOLVING APPROXIMATELY 10% OF PROSTATIC TISSUE (SEE COMMENT AND SYNOPSIS)
- EXTRAPROSTATIC EXTENSION IS PRESENT IN THE RIGHT BASE

"URETHRAL TISSUE," EXCISION

- PROSTATIC TISSUE WITH ADENOCARCINOMA, GLEASON GRADE 3+4 = SCORE 7

"PERI-PROSTATIC TISSUE," EXCISION

- PROSTATE TISSUE WITH HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA
- NO EVIDENCE OF ADENOCARCINOMA

SEMINAL VESICLES, BILATERAL, RADICAL PROSTATECTOMY

- NO EVIDENCE OF MALIGNANCY

LYMPH NODES, BILATERAL PELVIC, DISSECTION

- METASTATIC ADENOCARCINOMA IN ONE OF 11 LYMPH NODES (1/11), MEASURING LESS THAN 1 MM
- NO EXTRACAPSULAR EXTENSION PRESENT

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out B

Intraoperative Consultation:

An intraoperative non-microscopic consultation reading: "Brought to frozen section 'prostate,' consisting of a 42 gram prostate with attached bilateral seminal vesicles, measuring 4.5 x 4 x 4 cm. Tissue taken for tumor bank. Rest for permanents,

[page 2 of 4]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Microscopic Description and Comment:

Although we identified extraprostatic extension by the tumor in the right base, we did not identify tumor at the margin of the prostatectomy specimen. However, tumor is present in the separate urethral tissue arguing that the final margin status is actually positive. Clinical correlation with the sites of the tissues taken is recommended.

History:

The patient is a [REDACTED] year old man with adenocarcinoma, Gleason grade 4+3, score 7 of the prostate [REDACTED].
Operative procedure: Bilateral pelvic lymph node dissection with radical retropubic prostatectomy.

Specimen(s) Received:

A: BILATERAL PELVIC LYMPH NODES
B: PERI-PROSTATIC TISSUE
C: PROSTATE
D: URETHRAL TISSUE

Gross Description:

Received are four formalin-filled containers labeled with the patient's name [REDACTED]. The first container is labeled "bilateral pelvic lymph nodes." The container holds a piece of yellow-tan fatty fibrous tissue measuring 5 x 1.5 x 1.2 cm. The specimen is dissected to show multiple putative lymph nodes. Labeled A1 to A3 - putative lymph nodes; A4 - remaining dissection tissue. Jar 0.

The second container is labeled "periprostatic tissue." The container holds a piece of brown-tan fatty fibrous tissue measuring 0.9 x 0.4 x 0.3 cm. The specimen has an attached metal clip. Labeled B1. Jar 0.

The third container is labeled "prostate." The container holds a prostate that has been previously inked black, and has dimensions consistent with the intraoperative nonmicroscopic consultation. The specimen has attached seminal vesicles, the right seminal vesicle measures 3 x 1 x 0.9 cm, and the left seminal vesicle measures 3 x 1.2 x 0.8 cm. The specimen has a 1.5 x 0.5 x 0.5 cm defect in the right base, and a 1.5 x 0.5 x 0.5 cm defect in the left base consistent with tumor banking. The urethra is probe-patent. The prostate is sectioned to show whorling orange-tan parenchyma with dark yellow-orange discoloration. Labeled C1 - bladder neck shave margin; C2 and C3 - right apical margin; C4 and C5 - left apical margin; C6 - right seminal vesicle; C7 - left seminal vesicle; C8 and C9 - left apex (submitted in-toto); C10 to C21 - left base (submitted in-toto); C22 to C24 - right apex (submitted in-toto); C25 to C34 - right base (submitted in-toto). Jar 2.

The fourth container is labeled "urethral tissue." The container holds a piece of white-tan fibrous tissue measuring 1.2 x 0.7 x 0.3 cm. No definitive lumen is identified in the tissue. Bisected. Labeled D1. Jar 0.

SYNOPTIC WORKSHEET - PROSTATE CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The tumor type is adenocarcinoma, acinar type

INTRAGLANDULAR TUMOR EXTENT

The intraglandular tumor extent (reported as percent of prostate gland involved by carcinoma) = 10%

[page 3 of 4]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

GLEASON'S GRADE

The Gleason's Grade is 3+4
Tertiary pattern is absent

TUMOR LOCATION

The location of the tumor involves the
right base
right apex
left base

PERINEURAL INVASION

Perineural invasion is identified

LYMPH-VASCULAR INVASION

Lymph-Vascular Invasion is not identified

EXTRAPROSTATIC EXTENSION

Extraprostatic (extracapsular) extension is present
Extraprostatic (extracapsular) extension is focal (less than or equal to two 400x fields)
The tumor extends into the periprostatic soft tissues (specify site): right base

SEMINAL VESICLES

Seminal vesicles are free of tumor

SAMPLED SPECIMEN MARGINS

The separately submitted tissue labeled urethral tissue shows adenocarcinoma, Gleason Grade 3+4 = 7; see comment

NON-NEOPLASTIC PROSTATE

The non-neoplastic prostate shows PIN, high grade
The non-neoplastic prostate shows mild nodular hyperplasia with stromal nodule formation

METASTATIC LYMPH NODES

The lymph nodes are as follows (expressed as the number of metastatic nodes in relation to the total number of nodes examined)

Bilateral pelvic: 1/11

Extranodal extension by tumor metastases is absent

Diameter of largest lymph node metastasis, when present 1 (mm)

PRIMARY TUMOR (T)

Extraprostatic extension or microscopic invasion of bladder neck (T3a)

REGIONAL LYMPH NODES (N)

Metastasis in regional lymph node(s) (N1)

DISTANT METASTASIS

Distant metastasis cannot be assessed (not evaluated by any modality) (MX)

STAGE GROUPING

T3a/N1/MX/Gleason score 7 (Stage IV)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

[page 4 of 4]
Patient Name: [REDACTED]

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Surgical Pathology report is available on-line on

	Yes	No
HPA Discrepancy		/

END OF REPORT

Page 4 of 4

Source: NCI Genomic Data Commons file bb7325aa-c5f5-45e1-b890-42a5dada3d44 (TCGA-VP-A87J.03F4F8F1-ACE1-4391-85AC-A10B2F56CDD0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).